Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-6028, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-6028-01A (Primary Tumor).

[page 1 of 2]
Department of Pathology

Tissue Source Site (TSS) #: [REDACTED]

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY AND ADRENAL:

RENAL CELL CARCINOMA, CLEAR CELL TYPE, FUHRMAN NUCLEAR GRADE 4
(17.0 CM).

TUMOR EXTENDS INTO HILAR AND PERICAPSULAR ADIPOSE TISSUE AND INVOLVES
HILAR AND
PERICAPSULAR VESSELS.

Renal vein and ureteral margin, no tumor present.

Adrenal gland, no tumor present.

GROSS DESCRIPTION

(A) LEFT KIDNEY AND ADRENAL - A radical nephrectomy specimen (26.0 x 17.0 x 12.0 cm) including the kidney (24.0 x 16.0 x 10.0 cm), a segment of the renal artery, renal vein, and ureter, and adrenal gland (6.0 x 3.5 x 1.0 cm). There is a large variegated extensively necrotic mass (17.0 x 15.0 x 8.0 cm) in the upper pole of the kidney. Within this tumor there are multiple dark red and golden nodules, light tan friable nodules, and focal mahogany nodular areas. The tumor invades the perinephric adipose tissue and abuts the Gerota's fascia margin. The tumor invades into the renal sinus. Renal vein is grossly free of tumor. The tumor compresses the adrenal gland but does not invade. There are focal light tan well circumscribed nodules at the periphery of the tumor.

The adjacent kidney parenchyma is unremarkable. The pelvic calyceal system is compressed by the tumor but otherwise unremarkable. No lymph nodes are identified in the hilum of the kidney. The adrenal gland is grossly unremarkable.

Portions of the tumor have been submitted for a possible electron microscopy as well as for the vaccine protocol.

INK CODE: Black-Gerota's fascia.

SECTION CODE: A1, ureter and renal vein margin; A2, tumor adjacent to sinus; A3, tumor adjacent to Gerota's fascia margin; A4, tumor adjacent to Gerota's fascia margin; A5, tumor in renal sinus; A6, red tumor nodule in fat; A7, dark red tumor nodule in fat; A8, light tan tumor nodule adjacent to kidney; A9, fleshy tumor nodule; A10, granular light tan tumor nodule; A11, tumor adjacent to adrenal; A12, red tumor nodule in fat; A13, light tan tumor nodule; A14, light tan tumor nodule; A15, representative section of tumor; A16, representative section of tumor; A17, discrete tumor nodule at periphery; A18, tumor and adjacent kidney; A19, representative section of tumor; A20, representative section of kidney. [REDACTED]

CLINICAL HISTORY

History of left renal mass.

SNOMED CODES

[page 2 of 2]
Department of Pathology

[REDACTED]

Issue Source Site (TSS) #: [REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

T-71000, M-83123

Source: NCI Genomic Data Commons file 9ee5e86f-601f-431b-8a16-5ebf13a33bc1 (TCGA-CJ-6028.18425039-D833-4D0B-B21D-7A56CA5DCD0A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).